Surgical pathology report (de-identified scan), TCGA case TCGA-GR-7353, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-7353-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology and Microbiology

Name: [REDACTED]

Accession No: [REDACTED]

Hosp No: [REDACTED]

Acct No: [REDACTED]

DOB: [REDACTED]

Age: [REDACTED]

Sex: [REDACTED]

Date Taken: [REDACTED]

Date Received: [REDACTED]

Loc: [REDACTED]

Room: [REDACTED]

Submitted by: [REDACTED]

Client: [REDACTED]

Surgical Consult

Final Diagnosis:

LEFT CERVICAL LYMPH NODE, BIOPSY [REDACTED] LYMPH NODE
WITH DIFFUSE LARGE B-CELL LYMPHOMA, CLEAVED CELL TYPE (SEE COMMENT).
(B-DLCL-C) [REDACTED]

Diagnosis Comment:

The lymphoma cells have a germinal center cell phenotype.

[REDACTED]

Signed: [REDACTED]

History:

The patient is a [REDACTED]-year-old male with a left neck mass.

Source/Gross:

Received are 7 slides and 10 unstained slides labelled [REDACTED] from [REDACTED]
[REDACTED]

These materials were examined by all those listed to establish the diagnosis with the signature being the responsible staff pathologist

[REDACTED]

[page 2 of 2]
Name: [REDACTED] D.O.B. [REDACTED] Sex: M Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Consult

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE

B-Cell Markers		T-Cell Markers		Other Markers	
CD20(L26)	+	CD45RO(UCHL1)	ND	CD45(LCA)	ND
CD79a	ND	CD43(L60)	ND	CD30(Ber-H2)	ND
CD10	+	CD3(T3)	-	CD15(Leu M1)	ND
		CD5	-	BCL-2	-
				BCL-6	+
				Cyclin D1	-

INTERPRETATION: The paraffin markers indicate a B-cell phenotype.

Copy To: [REDACTED]

Source: NCI Genomic Data Commons file ff00a101-08ae-4fe3-9b3e-362acac04640 (TCGA-GR-7353.48694664-5B9F-4888-A14B-CA352A2378A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).